Gene-level copy-number profile of tumor specimen C3L-01046-01 (profiled together with C3L-01046-04) from CPTAC case C3L-01046, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 50.9 years (18,595 days).
Specimen C3L-01046-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Temporal Cortex; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1e89f5a8-791e-484c-b950-37d63b12aca5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-01046-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/c527ae5f-2989-439b-81b5-07ae415c7d6c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 9,561; copy number 2: 46,146; copy number 3: 2,958; copy number 4: 52; copy number 5: 33; copy number 6: 9; copy number 7: 77; copy number 8: 11; copy number 9: 21; copy number 28: 12; copy number 29: 9; copy number 32: 1; copy number 41: 9; copy number 44: 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:257,864–359,681, 2 genes (within-gene range 0–8): AP006222.1, AP006222.2.
- chr19:43,192,702–43,269,530, 3 genes: PSG4, CEACAMP10, PSG9.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 183 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:89,295–133,723, 1 gene, copy number 8 (within-gene range 4–8): AL627309.1.
- chr1:131,025–195,411, 10 genes, copy number 8: CICP27, AL627309.6, AL627309.7, AL627309.2, AL627309.5, RNU6-1100P, AL627309.4, FO538757.1, WASH9P, MIR6859-2.
- chr11:28,108,248–33,736,479, 83 genes, copy number 7–9 (within-gene range 4–9) (broad region; genes not listed).
- chr11:34,533,014–35,530,300, 17 genes, copy number 5–7: AL137224.1, LINC02707, EHF, AC087783.1, AL359999.1, APIP, PDHX, MIR1343, AL356215.1, CD44, CD44-AS1, AL133330.1, SLC1A2, SLC1A2-AS1, AC090625.1, AC090625.2, PAMR1.
- chr12:57,457,596–58,920,504, 54 genes, copy number 5–29 (within-gene range 2–29): AC022506.2, GLI1, ARHGAP9, MARS1, MIR6758, DDIT3, AC022506.1, MIR616, MBD6, DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1, AC020637.1, LINC02388, LRIG3.
- chr12:60,363,822–60,363,935, 1 gene, copy number 32: AC090022.1.
- chr12:61,708,259–62,279,150, 1 gene, copy number 5 (within-gene range 1–5): TAFA2.
- chr12:61,879,318–62,022,174, 2 genes, copy number 5: KRT8P19, RPS3P6.
- chr12:65,645,992–65,646,462, 1 gene, copy number 44: PCNPP3.
- chr12:68,686,951–69,224,242, 13 genes, copy number 6–41 (within-gene range 1–41): NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1.

Autosomal genes at a single copy (total copy number 1): 6,717. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
